Somatic mutation profile of tumor specimen TCGA-56-8625-01A (aliquot TCGA-56-8625-01A-11D-2395-08) from TCGA case TCGA-56-8625, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.2 years (24,188 days).
Specimen TCGA-56-8625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b87b92f-1dbf-4e84-aaf0-739913cbc7e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8625-10A (Blood Derived Normal), aliquot TCGA-56-8625-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2493a65-3f3b-411b-9c33-786e2ce13a0d

The open-access MAF lists 516 somatic variants for this specimen: 368 protein-altering or splice-affecting, 137 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 316, Silent 137, Nonsense Mutation 32, Splice Site 9, Frame Shift Del 6, Intron 4, Splice Region 4, RNA 3, 5'Flank 3, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | hotspot (GDC flag); catalogued as rs121913300, CM941205, COSV57297576, COSV57321266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB11 | c.3514G>A p.D1172N | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99792218; called by muse, mutect2, varscan2
- ACACB | c.841A>T p.R281W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100622902; called by muse, mutect2, varscan2
- ACOX1 | c.601G>T p.G201* | Nonsense Mutation (SNP) | VAF 43/134 reads (32%) | catalogued as COSV99503579; called by muse, mutect2, varscan2
- ADCY4 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV99353216; called by muse, mutect2, varscan2
- AGMO | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV100694145; called by muse, mutect2, varscan2
- AHNAK2 | c.14350C>T p.L4784F | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.605); catalogued as rs1349411132, COSV100317522, COSV60931888; called by muse, mutect2, varscan2
- ALDH1L1 | c.2082+1G>A p.X694_splice | Splice Site (SNP) | VAF 12/112 reads (11%) | catalogued as rs142903055, COSV99856843; called by muse, varscan2
- ALKBH3 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100236314, COSV57025074; called by muse, mutect2, varscan2
- ANKAR | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99854256; called by muse, varscan2
- ANKRD30A | c.1926C>A p.F642L (on ENST00000611781; = p.F586L on NM_052997.2) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100652988, COSV64605804, COSV64615083; called by muse, mutect2, varscan2
- AQP4 | c.930G>C p.K310N | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV101270517; called by muse, mutect2, varscan2
- ARHGAP21 | c.4400G>A p.R1467K | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.197); catalogued as COSV100256226; called by muse, mutect2, varscan2
- ARHGAP33 | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99138387; called by muse, mutect2, varscan2
- ARHGEF5 | c.1340C>G p.A447G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV99282831; called by muse, mutect2, varscan2
- ARHGEF9 | c.1188C>A p.N396K | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.974); catalogued as COSV99491803; called by muse, mutect2, varscan2
- ARIH2 | c.380C>G p.S127* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100711319; called by muse, mutect2, varscan2
- ARSA | c.684+1G>T p.X228_splice | Splice Site (SNP) | VAF 46/272 reads (17%) | catalogued as CS951348, COSV99332390; called by muse, mutect2, varscan2
- ASPH | c.1658G>A p.R553K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV101063872; called by muse, mutect2, varscan2
- ATG16L1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.742); catalogued as COSV100731318; called by muse, mutect2, varscan2
- ATIC | c.528G>C p.L176F | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52693683, COSV99377792; called by muse, mutect2, varscan2
- ATP2A1 | c.1128C>G p.I376M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100837298; called by muse, mutect2, varscan2
- ATP2C1 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242956141, CD128760, COSV100146699; called by muse, mutect2
- ATP6V1A | c.1040T>C p.M347T | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99850134; called by muse, mutect2
- ATP8B4 | c.3064C>G p.H1022D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV99465478; called by muse, mutect2, varscan2
- B3GAT3 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99605930; called by muse, mutect2, varscan2
- BACH2 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV57603269, COSV57610051; called by muse, varscan2
- BACH2 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99999487; called by muse, varscan2
- BARHL2 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs563173064, COSV100966054; called by muse, mutect2, varscan2
- BCKDK | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs886306366, COSV99570634; called by muse, mutect2, varscan2
- BEST3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs759773937, COSV58303887; called by muse, mutect2, varscan2
- BICRAL | c.1494G>T p.Q498H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100018068; called by muse, mutect2, varscan2
- BRINP3 | c.247C>A p.R83S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66543802; called by muse, mutect2, varscan2
- BRINP3 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV100818761; called by muse, mutect2, varscan2
- CACNA1B | c.1342T>A p.F448I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99497482; called by muse, mutect2, varscan2
- CALN1 | c.205G>C p.G69R (on ENST00000329008 / NM_001017440.3; = p.G111R on NM_031468.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100207039; called by muse, mutect2, varscan2
- CAMKK1 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99340274; called by muse, mutect2, varscan2
- CAPN2 | c.1376G>T p.R459M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.838); catalogued as COSV99688923; called by muse, mutect2, varscan2
- CBFA2T2 | c.907C>G p.H303D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV100656338; called by muse, mutect2, varscan2
- CBFB | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99325708; called by muse, mutect2, varscan2
- CCDC183 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs538949974, COSV100273340, COSV61041981; called by muse, mutect2, varscan2
- CCDC51 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 26/142 reads (18%) | catalogued as rs774877304, COSV99602840; called by muse, mutect2, varscan2
- CCDC97 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.283); catalogued as COSV99523734; called by muse, varscan2
- CCPG1 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51242928; called by muse, mutect2, varscan2
- CD96 | c.453A>G p.I151M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as rs780670315, COSV99342893; called by muse, mutect2, varscan2
- CD99L2 | c.289C>A p.H97N | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.185); catalogued as COSV100692235; called by muse, mutect2, varscan2
- CDCA3 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99976933; called by muse, mutect2, varscan2
- CDCA3 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57529194, COSV99976934; called by muse, mutect2, varscan2
- CDK12 | c.1778C>A p.S593Y | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV101420450; called by muse, mutect2, varscan2
- CES4A | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100110095; called by muse, mutect2, varscan2
- CGN | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99642331; called by muse, mutect2, varscan2
- CHIA | c.1292C>T p.A431V (on ENST00000343320; = p.A323V on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.21); catalogued as COSV100588669; called by muse, mutect2
- CLCN2 | c.1506C>T p.V502= | Splice Region (SNP) | VAF 10/71 reads (14%) | catalogued as rs762339307, COSV99658579; called by muse, mutect2, varscan2
- CLEC16A | c.2115G>C p.L705= | Splice Region (SNP) | VAF 8/130 reads (6%) | catalogued as COSV101278056; called by muse, mutect2
- CMSS1 | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs929589144, COSV101375594; called by muse, mutect2, varscan2
- CNKSR2 | c.2144C>G p.S715W | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99668531; called by muse, mutect2, varscan2
- CNN1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as rs375046434; called by muse, mutect2, varscan2
- CNTN2 | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1479712815, COSV100085004, COSV100085529; called by muse, mutect2, varscan2
- COL4A3 | c.4547G>A p.R1516Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368726092; called by muse, mutect2, varscan2
- COL5A3 | c.3568G>A p.G1190R | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99318912; called by muse, varscan2
- COMP | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs142274526; called by muse, mutect2, varscan2
- CPOX | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99939113; called by muse, mutect2, varscan2
- CRLF3 | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100158322; called by muse, mutect2, varscan2
- CRYBG3 | c.8902G>A p.E2968K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99477009; called by muse, mutect2, varscan2
- CSGALNACT2 | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100989820; called by muse, mutect2, varscan2
- CSMD3 | c.9470C>A p.A3157D (on ENST00000297405 / NM_001363185.1; = p.A2988D on NM_052900.3) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as COSV52102748; called by muse, mutect2
- CSMD3 | c.8722C>T p.Q2908* (on ENST00000297405 / NM_001363185.1; = p.Q2739* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 8/134 reads (6%) | catalogued as COSV52133217, COSV52177711; called by muse, mutect2
- CSPP1 | c.571C>T p.Q191* (on ENST00000676605; = p.Q150* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as CM140089, COSV99138561; called by muse, mutect2, varscan2
- CTNND1 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100650101; called by muse, mutect2, varscan2
- CUBN | c.3109A>G p.I1037V | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100912678; called by muse, mutect2, varscan2
- CUBN | c.2071A>G p.S691G | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV100912679; called by muse, mutect2, varscan2
- CUX2 | c.4115G>T p.R1372L | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99919675; called by muse, mutect2, varscan2
- CYP4F2 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV99686012; called by muse, mutect2, varscan2
- CYP4F2 | c.760C>A p.Q254K | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99171081; called by muse, mutect2, varscan2
- CYTH4 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as rs768254975, COSV99957934; called by muse, mutect2, varscan2
- DBF4 | c.1790A>G p.D597G | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99719309; called by muse, mutect2, varscan2
- DCAF8L1 | c.1045C>A p.Q349K | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs762197074, COSV101491463; called by muse, mutect2, varscan2
- DCLK3 | c.1675G>T p.D559Y | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101373976, COSV69365030; called by muse, mutect2, varscan2
- DEFB125 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 18/140 reads (13%) | catalogued as rs151148014; called by muse, mutect2, varscan2
- DGKZ | c.3086G>A p.R1029H (on ENST00000454345 / NM_001105540.2; = p.R841H on NM_003646.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs759011862, COSV58990412; called by muse, mutect2, varscan2
- DNAAF1 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100533674; called by muse, mutect2, varscan2
- DNAH3 | c.3413A>G p.D1138G | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs749209953; called by muse, mutect2, varscan2
- DNAJB8 | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as rs757171782, COSV100048305; called by muse, mutect2
- DNTTIP2 | c.2030A>G p.K677R | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239983584, COSV100785165; called by muse, mutect2, varscan2
- DOCK11 | c.4630G>T p.G1544* | Nonsense Mutation (SNP) | VAF 37/100 reads (37%) | catalogued as COSV99353831; called by muse, mutect2, varscan2
- DOT1L | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV101288649; called by muse, mutect2, varscan2
- DPP6 | c.413G>C p.S138T (on ENST00000377770 / NM_001364500.2; = p.S76T on NM_001936.5) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.297); catalogued as COSV100125588; called by muse, mutect2, varscan2
- DPYSL5 | c.936C>A p.S312R | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.261); catalogued as COSV99982389; called by muse, mutect2, varscan2
- DRC7 | c.1073G>A p.C358Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100395632; called by muse, mutect2, varscan2
- DSEL | c.2998A>T p.R1000* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100025645; called by muse, mutect2, varscan2
- DSG2 | c.1518C>G p.I506M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99853172; called by muse, mutect2, varscan2
- DUSP5 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100851894; called by muse, mutect2, varscan2
- DUSP7 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99623490; called by mutect2, varscan2
- E2F8 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100001496, COSV51464834; called by muse, mutect2, varscan2
- EGFL6 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100789884; called by muse, mutect2
- ELF4 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.071); catalogued as COSV100257366; called by muse, mutect2, varscan2
- EPHA7 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300929218, COSV100992397, COSV65169176; called by muse, mutect2
- ESPL1 | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs752710244, COSV57759948; called by muse, varscan2
- ESX1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 56/424 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs782015243, COSV101006441; called by muse, mutect2, varscan2
- ETAA1 | c.1712C>G p.S571* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99712770; called by muse, mutect2, varscan2
- EVI5L | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs1458390859, COSV99563156; called by muse, mutect2, varscan2
- EXO1 | c.1651G>T p.V551F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100799836; called by muse, mutect2, varscan2
- FBXO7 | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99832671; called by muse, mutect2, varscan2
- FCRL5 | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100708943; called by muse, mutect2, varscan2
- FLNA | c.3260G>T p.R1087L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV100774401, COSV100774722; called by muse, mutect2, varscan2
- FRY | c.3265G>C p.D1089H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100969279; called by muse, mutect2, varscan2
- FSIP2 | c.17878C>A p.R5960S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100555151; called by muse, mutect2, varscan2
- FSIP2 | c.19264G>T p.V6422F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100555156; called by muse, mutect2, varscan2
- GABPA | c.599G>T p.W200L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100702433; called by muse, mutect2, varscan2
- GEN1 | c.550A>G p.M184V | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs140068646, COSV100437973; called by muse, mutect2, varscan2
- GINM1 | c.882-1G>C p.X294_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100167803; called by muse, mutect2
- GINS1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs751622371, COSV99320105; called by mutect2, varscan2
- GLCE | c.355G>T p.G119W | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99962375; called by muse, mutect2, varscan2
- GLT6D1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs867118146, COSV65627291; called by muse, mutect2, varscan2
- GMPPB | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV100246580; called by muse, mutect2
- GORAB | c.164A>T p.D55V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs1449481527, COSV100883767; called by muse, mutect2, varscan2
- GTPBP4 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100672664, COSV99054322; called by muse, mutect2, varscan2
- HCN1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV57536526; called by muse, mutect2, varscan2
- HDLBP | c.2843G>A p.C948Y | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs776400845, COSV100190645; called by muse, mutect2, varscan2
- HELZ2 | c.5836G>T p.E1946* (on ENST00000467148 / NM_001037335.2; = p.E1377* on NM_033405.3) | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV101427564; called by muse, varscan2
- HEPH | c.198G>T p.K66N (on ENST00000343002; = p.K120N on NM_138737.5) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV57967862; called by muse, mutect2, varscan2
- HEPH | c.3055G>A p.A1019T (on ENST00000343002; = p.A752T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.838); catalogued as COSV100294853; called by muse, mutect2, varscan2
- HNRNPL | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as COSV99670304; called by muse, mutect2, varscan2
- HTATSF1 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); catalogued as rs767612293, COSV99511651; called by muse, mutect2, varscan2
- HUWE1 | c.2183A>G p.E728G | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99472368; called by muse, mutect2, varscan2
- IDH3G | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99473135; called by muse, mutect2, varscan2
- IGF2R | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs377184247; called by muse, mutect2, varscan2
- IGHV3-20 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.047); catalogued as rs113765033; called by muse, mutect2, varscan2
- IMPG2 | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV99515579; called by muse, varscan2
- INPP5D | c.556G>T p.D186Y (on ENST00000445964 / NM_001017915.3; = p.D185Y on NM_005541.5) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100856797; called by muse, mutect2, varscan2
- INVS | c.2859G>C p.W953C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV99317539; called by muse, mutect2, varscan2
- IPO7 | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV101121824, COSV65684265; called by muse, mutect2, varscan2
- IRX5 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs768213705, COSV100315825; called by muse, mutect2, varscan2
- ISLR | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99997327; called by muse, mutect2
- ITGA7 | c.3458G>A p.R1153Q (on ENST00000555728; = p.R1109Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.099); catalogued as rs200827653, COSV99145823; called by muse, mutect2, varscan2
- ITGB5 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV56146443; called by muse, mutect2, varscan2
- ITIH2 | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100623294; called by muse, mutect2, varscan2
- KBTBD12 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs1250887735, COSV100675432; called by muse, mutect2
- KCNH3 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1223372385, COSV99235234; called by muse, mutect2, varscan2
- KCTD16 | c.132A>G p.I44M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV101568808; called by muse, mutect2, varscan2
- KDELR3 | c.247C>A p.R83S | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV53248441, COSV99318210; called by muse, mutect2, varscan2
- KDM2A | c.1462C>G p.L488V | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV101284643; called by muse, mutect2, varscan2
- KIAA1109 | c.14962G>T p.G4988C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99163613; called by muse, mutect2, varscan2
- KIF23 | c.364A>G p.M122V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs200683749, COSV99532339; called by muse, mutect2, varscan2
- KIFC2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV100023791; called by muse, mutect2
- KRBA1 | c.1253C>G p.S418C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55439950; called by muse, mutect2, varscan2
- KRI1 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV100470126; called by muse, mutect2, varscan2
- KRT82 | c.684C>T p.D228= | Splice Region (SNP) | VAF 11/55 reads (20%) | catalogued as rs200149668, COSV57786728; called by muse, mutect2, varscan2
- L1CAM | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs201642622, COSV100649149; called by muse, mutect2, varscan2
- LAMB3 | c.1417G>C p.A473P | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100620339; called by muse, mutect2, varscan2
- LHFPL6 | c.278G>T p.C93F | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101095295; called by muse, mutect2, varscan2
- LHX4 | c.250C>A p.R84S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM081323, COSV99761535, COSV99761881; called by muse, mutect2, varscan2
- LILRB3 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV54433649; called by muse, mutect2, varscan2
- LINGO2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV100430562; called by muse, mutect2, varscan2
- LRCH3 | c.594G>C p.L198F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100605085; called by muse, mutect2, varscan2
- LRIF1 | c.2032C>A p.H678N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100870844; called by muse, mutect2, varscan2
- LRRC4C | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs866609240, COSV53424369, COSV53433884, COSV99538235; called by muse, mutect2, varscan2
- LRSAM1 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100031498; called by muse, mutect2, varscan2
- LTBP1 | c.2464C>G p.Q822E (on ENST00000404816 / NM_206943.4; = p.Q496E on NM_000627.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100617161; called by muse, mutect2, varscan2
- LYPD3 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs748210378, COSV99747026; called by muse, mutect2, varscan2
- LZTS1 | c.945C>A p.N315K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99742984; called by muse, mutect2, varscan2
- MAGEA4 | c.892G>T p.V298F | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV99367486; called by muse, mutect2, varscan2
- MAGED1 | c.46-1G>T p.X16_splice | Splice Site (SNP) | VAF 76/100 reads (76%) | catalogued as COSV100431584; called by muse, varscan2
- MAMLD1 | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as COSV99476005; called by muse, mutect2, varscan2
- MAN2B2 | c.898G>C p.A300P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as COSV99577422; called by muse, mutect2, varscan2
- MANBA | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.22); catalogued as COSV99898716; called by muse, mutect2, varscan2
- MAPKBP1 | c.1999-1G>C p.X667_splice (on ENST00000456763 / NM_001128608.2; = p.X661_splice on NM_014994.3) | Splice Site (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99529440; called by muse, mutect2, varscan2
- MASP1 | c.175A>T p.K59* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | catalogued as COSV99397183; called by muse, mutect2, varscan2
- MBOAT7 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs772530371, COSV99824822; called by muse, mutect2, varscan2
- MCF2 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100644784; called by muse, mutect2, varscan2
- ME2 | c.1057-1G>T p.X353_splice | Splice Site (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100360780; called by mutect2, varscan2
- MED20 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV99539855; called by muse, mutect2, varscan2
- MED21 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.238); catalogued as COSV99282064; called by muse, mutect2
- MEFV | c.985C>A p.R329S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV54819090, COSV54827097, COSV99560859; called by mutect2, varscan2
- MEI1 | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1448940976, COSV100299937; called by muse, mutect2, varscan2
- MKNK1 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100361242; called by muse, mutect2, varscan2
- MMP15 | c.539A>T p.Q180L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99539472; called by muse, varscan2
- MNAT1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.024); catalogued as COSV99710222; called by muse, mutect2, varscan2
- MOCOS | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs760399968, COSV99732638, COSV99733375; called by muse, mutect2, varscan2
- MORC4 | c.138C>A p.S46R | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV99717192; called by muse, mutect2, varscan2
- MRPL50 | c.456G>C p.L152F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100879807, COSV100879816; called by muse, mutect2, varscan2
- MRPS25 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.716); catalogued as COSV99507729; called by muse, mutect2
- MST1R | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs760389915, COSV56572702; called by muse, mutect2, varscan2
- MTERF4 | c.707A>T p.Y236F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV99612592; called by muse, mutect2, varscan2
- MTMR1 | c.1560G>T p.E520D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100953097; called by muse, mutect2
- MYL4 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.101); catalogued as COSV100733117; called by muse, mutect2, varscan2
- MYPN | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV62731979; called by muse, mutect2, varscan2
- NAV3 | c.4765A>T p.T1589S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99890998; called by muse, mutect2, varscan2
- NBAS | c.2608G>A p.G870R | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99869721; called by muse, mutect2, varscan2
- NCKAP1L | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.61); catalogued as COSV99515090; called by muse, mutect2, varscan2
- NCR3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV99279043; called by muse, mutect2, varscan2
- NETO1 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV100198744; called by muse, mutect2, varscan2
- NLRP14 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100204979; called by muse, mutect2
- NLRX1 | c.2044C>T p.H682Y | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.468); catalogued as rs756636291, COSV99424248; called by muse, mutect2, varscan2
- NPAP1 | c.2237C>A p.T746N | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.839); catalogued as rs755626072, COSV100275404; called by muse, mutect2, varscan2
- NTNG2 | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 23/111 reads (21%) | catalogued as COSV100647443; called by muse, mutect2, varscan2
- NUBP2 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99236520; called by muse, mutect2, varscan2
- NUP214 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV100845285; called by muse, mutect2, varscan2
- NUP42 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.476); catalogued as COSV99331034; called by muse, mutect2
- NXPH2 | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99740612; called by muse, mutect2, varscan2
- NYNRIN | c.2335T>C p.F779L | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101230594; called by muse, mutect2
- OAS1 | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as COSV52537515, COSV52538234, COSV52538343; called by muse, mutect2, varscan2
- OLFML2A | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.073); catalogued as COSV99992602; called by muse, mutect2, varscan2
- OR10A3 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100660270; called by muse, mutect2, varscan2
- OR10G2 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs750094846, COSV101606952; called by muse, mutect2, varscan2
- OR10G8 | c.792G>T p.R264S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.217); catalogued as COSV101461838, COSV70909599; called by muse, mutect2, varscan2
- OR1Q1 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99939238; called by muse, mutect2, varscan2
- OR1S2 | c.486G>A p.W162* | Nonsense Mutation (SNP) | VAF 30/185 reads (16%) | catalogued as rs1269202411, COSV100224205; called by muse, mutect2, varscan2
- OR2F2 | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101283816; called by muse, mutect2, varscan2
- OR2L13 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV100813754, COSV63555581; called by muse, mutect2, varscan2
- OR2M7 | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100522541, COSV58739725; called by muse, mutect2, varscan2
- OR56A1 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100360470; called by muse, mutect2, varscan2
- OR5AN1 | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); catalogued as COSV100004338; called by muse, mutect2
- OR5B3 | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100511991; called by muse, mutect2, varscan2
- OR5H6 | c.576C>A p.H192Q (on ENST00000642105; = p.H176Q on NM_001005479.2) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101051772; called by muse, mutect2
- OR5H6 | c.578T>A p.F193Y (on ENST00000642105; = p.F177Y on NM_001005479.2) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV101051773; called by muse, mutect2
- OR5R1 | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100393442; called by muse, mutect2, varscan2
- OTOGL | c.5746G>C p.E1916Q (on ENST00000547103; = p.E1907Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as COSV100087269; called by muse, mutect2, varscan2
- PARP11 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99959025; called by muse, mutect2
- PARP3 | c.1312T>A p.Y438N | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101290666; called by muse, mutect2, varscan2
- PARVG | c.986C>A p.A329D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.027); catalogued as rs1249598044, COSV100796078, COSV63562261; called by muse, mutect2, varscan2
- PAX3 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs551614431, COSV100399635; called by muse, mutect2, varscan2
- PCDH15 | c.4813A>G p.I1605V (on ENST00000644397 / NM_001354429.2; = p.I1547V on NM_001142771.2) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.211); catalogued as COSV100904365; called by muse, mutect2, varscan2
- PCDHB7 | c.1592T>A p.V531E | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV50760070, COSV99177544; called by muse, mutect2, varscan2
- PDILT | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as COSV100199393; called by muse, mutect2, varscan2
- PELI1 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100735122; called by muse, mutect2
- PGGT1B | c.665C>A p.S222* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99685921; called by muse, mutect2, varscan2
- PHEX | c.1811C>A p.S604Y | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101039631; called by muse, mutect2, varscan2
- PHKA2 | c.1405C>A p.H469N | Missense Mutation (SNP) | VAF 121/256 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1234231339, COSV101177064; called by muse, mutect2, varscan2
- PHLDB1 | c.3230C>T p.P1077L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100616543; called by muse, mutect2, varscan2
- PIK3R2 | c.1753G>C p.G585R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV99717418; called by muse, mutect2, varscan2
- PKDREJ | c.4339T>A p.L1447M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1569270500, COSV53549533, COSV53550928, COSV99478902; called by muse, mutect2, varscan2
- PLOD3 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as COSV99778022; called by muse, mutect2, varscan2
- PLXNA3 | c.1757T>A p.L586Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.843); catalogued as COSV100859985; called by muse, mutect2, varscan2
- PLXNB3 | c.1745C>A p.T582N | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV100737446; called by muse, mutect2, varscan2
- PNPLA5 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.259); catalogued as rs1459512775, COSV53376092; called by muse, mutect2, varscan2
- POU3F2 | c.8C>A p.T3N | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100099183; called by mutect2, varscan2
- PPP4R3B | c.1775G>T p.R592L (on ENST00000616407 / NM_001122964.3; = p.R507L on NM_020463.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99702024; called by muse, mutect2, varscan2
- PRDM9 | c.2304G>T p.R768S | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99690456; called by muse, varscan2
- PRMT2 | c.1232G>A p.W411* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99388662; called by muse, mutect2, varscan2
- PRORP | c.81_82del p.Y28Cfs*21 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs905020895; called by mutect2, pindel, varscan2
- PRSS23 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV99722411; called by muse, mutect2, varscan2
- PRSS23 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.353); catalogued as COSV99722415; called by muse, mutect2, varscan2
- PRTFDC1 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV100196930; called by muse, mutect2, varscan2
- PSPH | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV99304272; called by muse, mutect2, varscan2
- PTPN4 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.345); catalogued as COSV99750262; called by muse, mutect2, varscan2
- PTPRB | c.3933C>A p.N1311K | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.232); catalogued as COSV99717413; called by muse, mutect2, varscan2
- PTPRH | c.2672C>A p.A891E | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99671001; called by muse, mutect2, varscan2
- RAG1 | c.1403C>A p.A468D | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100200909; called by muse, mutect2, varscan2
- RALGAPA1 | c.4957G>T p.V1653L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99354762; called by muse, mutect2, varscan2
- RAPGEFL1 | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs749562431, COSV99228979; called by muse, mutect2, varscan2
- RASGRF2 | c.2904C>T p.L968= | Splice Region (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99429234; called by muse, mutect2, varscan2
- RASGRP2 | c.1566C>G p.I522M | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV62451489; called by muse, mutect2, varscan2
- RBL1 | c.2551A>T p.M851L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV100727051; called by muse, mutect2, varscan2
- RBL2 | c.1810C>G p.P604A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.589); catalogued as COSV100043630; called by muse, mutect2, varscan2
- RCOR1 | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99217470; called by muse, mutect2, varscan2
- RGS4 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1482287208, COSV63357011, COSV63358209; called by muse, mutect2, varscan2
- RHOXF2 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV101002765, COSV101002783; called by muse, mutect2, varscan2
- RINL | c.733G>T p.G245* (on ENST00000591812 / NM_001195833.2; = p.G131* on NM_198445.4) | Nonsense Mutation (SNP) | VAF 31/155 reads (20%) | catalogued as COSV100531170, COSV61574587; called by muse, mutect2, varscan2
- RRAGB | c.200G>T p.R67I | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV99469339; called by muse, mutect2, varscan2
- RREB1 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1395752098, COSV100619365; called by muse, mutect2, varscan2
- RRP1 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV101513869; called by muse, mutect2, varscan2
- RSPH1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99370489; called by muse, mutect2, varscan2
- RXRA | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV100709261; called by muse, mutect2, varscan2
- SAGE1 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.41); catalogued as rs781798413, COSV61012362; called by muse, mutect2, varscan2
- SCN4A | c.1856G>A p.G619D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV71129500; called by muse, mutect2, varscan2
- SDHA | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99371676; called by muse, mutect2, varscan2
- SEH1L | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV100040098; called by muse, mutect2, varscan2
- SEMA3C | c.1717A>G p.R573G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.146); catalogued as COSV99543016; called by muse, mutect2, varscan2
- SETDB1 | c.3617C>A p.S1206Y | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV99644647; called by muse, mutect2, varscan2
- SETX | c.6934G>A p.D2312N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99809769; called by muse, mutect2
- SIPA1L2 | c.2694G>T p.R898S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV99478260; called by muse, mutect2, varscan2
- SIPA1L2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV99478263; called by muse, mutect2, varscan2
- SKOR1 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100408355, COSV58244028; called by muse, mutect2, varscan2
- SLC25A41 | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58599578; called by mutect2, varscan2
- SLC26A1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs371815691; called by muse, mutect2
- SLC41A1 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100900392; called by muse, varscan2
- SLC9A2 | c.1128C>G p.I376M | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99296258; called by muse, mutect2, varscan2
- SLC9C2 | c.1703G>A p.W568* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100876756; called by muse, mutect2, varscan2
- SLCO1C1 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56870188; called by muse, mutect2, varscan2
- SMARCC2 | c.1402T>C p.F468L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99911339; called by muse, mutect2, varscan2
- SMC1A | c.1417A>T p.I473F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV100447389; called by muse, mutect2, varscan2
- SNAP47 | c.488G>C p.R163P | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100248148; called by muse, mutect2, varscan2
- SNX5 | c.636G>C p.E212D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1427034923, COSV100899002; called by muse, mutect2, varscan2
- SORCS1 | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.333); catalogued as COSV99546432, COSV99551055; called by muse, mutect2
- SOX3 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as COSV100983705; called by muse, mutect2, varscan2
- SP140 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100613792; called by muse, mutect2, varscan2
- SPTB | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs147984790; called by muse, mutect2, varscan2
- SRCAP | c.3185C>T p.P1062L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1438657572, COSV99350143; called by muse, mutect2, varscan2
- SRM | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV100978952; called by muse, mutect2
- SSH2 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99282112; called by muse, mutect2, varscan2
- SSRP1 | c.2114C>A p.S705* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as COSV99554918; called by muse, mutect2, varscan2
- ST6GAL2 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 41/212 reads (19%) | PolyPhen possibly damaging (0.787); catalogued as COSV100867885; called by muse, mutect2, varscan2
- STIL | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV54547328, COSV99680962; called by muse, mutect2, varscan2
- STOML2 | c.330G>C p.M110I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100521321; called by muse, mutect2, varscan2
- STUM | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs768259793, COSV100828257; called by muse, mutect2
- SYNJ2 | c.4378A>G p.K1460E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs930212710, COSV100840209; called by muse, mutect2, varscan2
- SYT4 | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs750239570, COSV54904869, COSV99673839; called by muse, mutect2, varscan2
- SYTL5 | c.2118G>C p.K706N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99937248; called by muse, mutect2, varscan2
- TBL1XR1 | c.1265C>G p.S422C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV101467759; called by muse, varscan2
- TDRD3 | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV99540338; called by muse, mutect2, varscan2
- TEKT3 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.07); catalogued as rs147750959; called by muse, mutect2, varscan2
- TET3 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV101327818; called by muse, mutect2, varscan2
- TEX2 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.273); catalogued as COSV99367112; called by muse, varscan2
- TGM6 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99171789; called by muse, mutect2, varscan2
- TLR5 | c.2352C>A p.N784K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100643284; called by muse, mutect2, varscan2
- TMEM213 | c.240C>A p.S80R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100023111; called by muse, mutect2, varscan2
- TRHDE | c.2378G>C p.G793A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as COSV99670830; called by muse, mutect2, varscan2
- TRIM55 | c.784G>T p.V262F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs751272504, COSV52546908, COSV99396800; called by muse, mutect2, varscan2
- TRPC5 | c.207G>T p.L69F | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53301532; called by muse, mutect2, varscan2
- TTC30A | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.609); catalogued as COSV100826187; called by muse, mutect2, varscan2
- TTLL3 | c.817T>A p.C273S | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100047526; called by muse, mutect2, varscan2
- TTN | c.41518G>C p.E13840Q (on ENST00000591111; = p.E6416Q on NM_003319.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | PolyPhen probably damaging (0.997); catalogued as COSV100612809; called by muse, mutect2, varscan2
- TTN | c.19278G>C p.Q6426H (on ENST00000591111; = p.Q5499H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | PolyPhen benign (0.001); catalogued as rs1354673910, COSV100612810; called by muse, mutect2, varscan2
- TTN | c.15028G>T p.D5010Y (on ENST00000591111; = p.D4083Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | PolyPhen probably damaging (1); catalogued as COSV100612811, COSV59863267; called by muse, mutect2, varscan2
- TTN | c.9952G>T p.G3318C (on ENST00000591111; = p.G3272C on NM_003319.4) | Missense Mutation (SNP) | VAF 22/115 reads (19%) | PolyPhen probably damaging (1); catalogued as COSV100612813; called by muse, mutect2, varscan2
- TTN | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | PolyPhen probably damaging (0.987); catalogued as COSV59908711; called by muse, mutect2, varscan2
- TYW1 | c.560A>T p.H187L | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100658690; called by muse, mutect2, varscan2
- UBQLN2 | c.1319C>A p.P440Q | Missense Mutation (SNP) | VAF 95/140 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763131369, COSV100592719; called by muse, mutect2, varscan2
- UGT2B11 | c.370A>T p.R124* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV101485251; called by muse, mutect2, varscan2
- UNC5D | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV54785593, COSV99775245; called by muse, mutect2, varscan2
- USF2 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs753576519, COSV99723404; called by muse, mutect2, varscan2
- USF3 | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100325263, COSV57072686; called by muse, mutect2, varscan2
- USP19 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100026163; called by muse, mutect2, varscan2
- UTP20 | c.341T>G p.L114W | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99881640; called by muse, mutect2, varscan2
- VAX2 | c.707C>G p.S236* | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | catalogued as COSV52267160, COSV99313457; called by muse, mutect2
- WBP2NL | c.222G>C p.M74I | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100173783; called by muse, mutect2, varscan2
- WDR7 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs573385149, COSV54355492, COSV99589482; called by muse, mutect2, varscan2
- WDR70 | c.917+1G>A p.X306_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as rs753882733, COSV54273646, COSV99458835; called by muse, mutect2, varscan2
- WDR72 | c.154-1G>C p.X52_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100854458; called by muse, varscan2
- WDR86 | c.620C>A p.T207K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as COSV100561289; called by muse, mutect2
- XIAP | c.77A>G p.E26G | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100848872; called by muse, mutect2, varscan2
- XPOT | c.730T>C p.C244R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100225523; called by muse, mutect2, varscan2
- YARS1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774209874, COSV100993399; called by muse, mutect2, varscan2
- ZDHHC17 | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as COSV100602119; called by muse, mutect2, varscan2
- ZFHX3 | c.3281A>T p.N1094I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99212240; called by muse, mutect2, varscan2
- ZFP1 | c.1091G>T p.R364M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV100182030; called by muse, mutect2, varscan2
- ZFP37 | c.949G>T p.G317W | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100953268; called by muse, mutect2, varscan2
- ZG16B | c.531G>C p.K177N | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs1375319087, COSV101206758; called by muse, mutect2, varscan2
- ZMYM6 | c.3796G>C p.E1266Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.244); catalogued as COSV100593183, COSV64120612; called by muse, mutect2, varscan2
- ZNF10 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99940004; called by muse, mutect2, varscan2
- ZNF182 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs782543305, COSV59358213; called by muse, mutect2, varscan2
- ZNF233 | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV100492264; called by muse, mutect2, varscan2
- ZNF280A | c.1532G>T p.S511I | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV100131055; called by muse, mutect2, varscan2
- ZNF283 | c.1613C>T p.T538I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100190571; called by muse, mutect2, varscan2
- ZNF404 | c.399T>A p.C133* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100182567; called by muse, mutect2, varscan2
- ZNF507 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100321839; called by muse, mutect2, varscan2
- ZNF566 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101091399; called by muse, mutect2, varscan2
- ZSCAN25 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs755130158, COSV53552431; called by muse, mutect2, varscan2
- ALAS2 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2
- ANKRD13A | c.1668_1669del p.A557Hfs*21 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- CCP110 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2
- CEP89 | c.886+1del p.X296_splice | Splice Site (DEL) | VAF 26/115 reads (23%) | called by mutect2, pindel, varscan2
- DDC | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.347); called by muse, mutect2
- GABRP | c.475del p.A159Hfs*35 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- IGHV3-20 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- INSIG2 | c.244+1dup | Frame Shift Ins (INS) | VAF 12/81 reads (15%) | called by mutect2, pindel, varscan2
- KIR2DL1 | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- LRP1B | c.9875del p.P3292Lfs*121 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- MYO9A | c.3658del p.R1220Vfs*8 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- NINL | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); called by muse, mutect2
- RBP3 | c.3037G>T p.G1013* | Nonsense Mutation (SNP) | VAF 44/111 reads (40%) | called by muse, mutect2, varscan2
- RDM1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RELN | c.807del p.S270Qfs*28 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- SUPT20HL1 | c.720G>C p.Q240H | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.573); called by muse, mutect2
- TRAV1-1 | c.125A>T p.Q42L | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ABCB1 | c.1317G>A p.L439= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99713064; called by muse, mutect2, varscan2
- ACACB | c.639C>T p.R213= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs781384319, COSV58146973; called by muse, mutect2
- ACE2 | c.27C>T p.L9= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as rs1463669655, COSV53023720, COSV99382573; called by muse, mutect2
- ACO1 | c.1758G>C p.L586= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100008133, COSV59381511; called by muse, mutect2, varscan2
- AFF2 | c.2976C>A p.A992= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV99664017; called by muse, mutect2, varscan2
- AHNAK2 | c.3825G>A p.L1275= | Silent (SNP) | VAF 38/208 reads (18%) | catalogued as rs781236575, COSV100317523, COSV60921541; called by muse, mutect2, varscan2
- ALPP | c.165C>A p.A55= | Silent (SNP) | VAF 39/184 reads (21%) | catalogued as COSV101235144; called by muse, mutect2, varscan2
- ARHGAP31 | c.1395C>T p.V465= | Silent (SNP) | VAF 24/228 reads (11%) | catalogued as COSV99957116; called by muse, mutect2, varscan2
- ASXL2 | c.345C>T p.S115= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as COSV99711107; called by muse, mutect2, varscan2
- ATP1A4 | c.2358G>T p.L786= | Silent (SNP) | VAF 45/235 reads (19%) | catalogued as COSV100927552; called by muse, mutect2, varscan2
- ATP6V1C2 | c.984C>G p.L328= (on ENST00000272238 / NM_001039362.2; = p.L282= on NM_144583.4) | Silent (SNP) | VAF 9/90 reads (10%) | called by mutect2, varscan2
- BANP | c.1005G>A p.R335= (on ENST00000286122; = p.R304= on NM_017869.4) | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as COSV99621556; called by muse, mutect2, varscan2
- BRD2 | c.1725G>A p.G575= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV100875694; called by muse, mutect2, varscan2
- BRD9 | c.1266G>C p.A422= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as COSV100057226; called by muse, varscan2
- CADPS | c.3804G>C p.V1268= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99338246; called by muse, mutect2, varscan2
- CATSPERD | c.633G>A p.A211= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV101062393; called by mutect2, varscan2
- CCDC142 | c.141G>C p.P47= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV99282178; called by muse, mutect2, varscan2
- CD177 | c.24C>A p.A8= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as COSV100945959, COSV65121119; called by muse, mutect2, varscan2
- CEACAM8 | c.687C>T p.V229= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as COSV99747604; called by muse, mutect2, varscan2
- CEP162 | c.831A>T p.G277= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100002807; called by muse, mutect2, varscan2
- CEP250 | c.6477G>T p.L2159= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV100698930, COSV61168996; called by muse, mutect2, varscan2
- CLDN2 | c.147C>A p.G49= | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as COSV100390106; called by muse, mutect2, varscan2
- COBLL1 | c.759G>A p.A253= (on ENST00000392717; = p.A215= on NM_014900.5) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs1335545333, COSV99527917, COSV99528429; called by muse, mutect2
- COL6A3 | c.5412G>A p.E1804= | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as COSV99798316; called by muse, mutect2, varscan2
- COPB1 | c.2115A>G p.A705= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as COSV99999581; called by muse, mutect2, varscan2
- COPG1 | c.1053G>T p.T351= | Silent (SNP) | VAF 12/135 reads (9%) | catalogued as COSV59114417, COSV59116784; called by muse, mutect2
- CP | c.1878C>T p.F626= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99224109; called by muse, mutect2, varscan2
- CUX1 | c.648C>T p.T216= (on ENST00000292535 / NM_181552.4; = p.T227= on NM_001913.5) | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1554491446, COSV99471520; called by muse, mutect2, varscan2
- DAO | c.225C>G p.L75= | Silent (SNP) | VAF 71/396 reads (18%) | catalogued as COSV99948610; called by muse, mutect2, varscan2
- DAXX | c.1125C>G p.V375= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99802104; called by muse, mutect2, varscan2
- DAXX | c.996C>T p.L332= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV56470458, COSV99802106; called by muse, mutect2, varscan2
- DHX36 | c.3001C>A p.R1001= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV100273596, COSV100273973; called by muse, mutect2, varscan2
- DISP1 | c.4380A>G p.P1460= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99451020; called by muse, mutect2, varscan2
- DMAC2L | c.577C>T p.L193= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99816439; called by muse, mutect2, varscan2
- DNAH5 | c.10002C>T p.V3334= | Silent (SNP) | VAF 29/175 reads (17%) | catalogued as COSV54247153; called by muse, mutect2, varscan2
- DOK2 | c.750C>G p.P250= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV99374726; called by muse, mutect2, varscan2
- DUSP8 | c.81G>A p.P27= | Silent (SNP) | VAF 50/243 reads (21%) | catalogued as rs768306901, COSV100524370; called by muse, mutect2, varscan2
- EFL1 | c.1461G>T p.V487= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV51610119; called by muse, mutect2, varscan2
- ELF4 | c.1393C>T p.L465= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV100257364; called by muse, mutect2, varscan2
- FBXL2 | c.552G>A p.L184= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV52144021; called by muse, mutect2, varscan2
- FBXO4 | c.582G>T p.V194= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as COSV99715158; called by muse, mutect2, varscan2
- FGD1 | c.2676C>T p.I892= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV100911072; called by muse, mutect2
- FKBP6 | c.249A>G p.L83= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV99333963; called by muse, mutect2, varscan2
- FLNA | c.6207C>A p.I2069= (on ENST00000369850 / NM_001110556.2; = p.I2061= on NM_001456.3) | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100774720; called by muse, mutect2, varscan2
- FLNA | c.3261C>T p.R1087= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV100774721; called by muse, mutect2, varscan2
- GABRG2 | c.1038T>A p.S346= (on ENST00000361925 / NM_001375343.1; = p.S306= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100729695; called by muse, mutect2, varscan2
- GFM1 | c.435C>G p.L145= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs765316378, COSV99962681, COSV99962899; called by muse, mutect2, varscan2
- GPR162 | c.631C>A p.R211= | Silent (SNP) | VAF 70/131 reads (53%) | catalogued as COSV99163771; called by muse, mutect2, varscan2
- HCFC1 | c.5829G>T p.P1943= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV100129027; called by muse, mutect2, varscan2
- HECW1 | c.3180T>C p.N1060= | Silent (SNP) | VAF 44/177 reads (25%) | catalogued as COSV101223543; called by muse, mutect2, varscan2
- HEPH | c.3054G>T p.R1018= (on ENST00000343002; = p.R751= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV100294851; called by muse, mutect2, varscan2
- HTR2A | c.705C>A p.V235= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV101096693; called by muse, mutect2, varscan2
- IGSF9 | c.690G>A p.V230= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100829626; called by muse, mutect2, varscan2
- INCENP | c.858G>A p.L286= | Silent (SNP) | VAF 31/204 reads (15%) | catalogued as rs759410705, COSV99611041; called by muse, mutect2, varscan2
- ITGB5 | c.528G>C p.R176= | Silent (SNP) | VAF 27/247 reads (11%) | catalogued as COSV99950695; called by muse, mutect2, varscan2
- ITPR1 | c.6921C>T p.P2307= (on ENST00000354582; = p.P2252= on NM_002222.7) | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs762235869, COSV100231190; called by muse, mutect2, varscan2
- KRTAP10-4 | c.1203C>G p.L401= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV100553572; called by muse, mutect2
- LAMA5 | c.342A>G p.A114= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99440067; called by muse, mutect2, varscan2
- LILRA1 | c.330C>A p.P110= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV99251905; called by muse, varscan2
- LMF2 | c.1470G>C p.L490= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV99327567; called by muse, mutect2, varscan2
- LRP1B | c.1857C>A p.G619= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV101257028; called by muse, mutect2, varscan2
- LRRFIP1 | c.1695G>A p.S565= (on ENST00000392000 / NM_001137552.2; = p.S541= on NM_004735.4) | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs549911870, COSV99790766; called by muse, mutect2
- LYPD3 | c.90C>T p.A30= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1319134967, COSV99747022; called by muse, mutect2, varscan2
- MAGED1 | c.1797C>T p.L599= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100431586; called by muse, mutect2
- MAP2 | c.618T>G p.T206= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV52285788; called by muse, mutect2, varscan2
- ME3 | c.1014C>T p.G338= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs757380399, COSV62774557, COSV62775919; called by muse, mutect2
- MMP15 | c.567G>C p.L189= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99539475; called by muse, varscan2
- MMUT | c.213C>G p.P71= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV99222340, COSV99222637; called by muse, mutect2, varscan2
- MPL | c.1242G>A p.S414= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs544064034, COSV65244840; called by muse, mutect2, varscan2
- MRPL2 | c.684G>T p.L228= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV99431937; called by muse, mutect2, varscan2
- MS4A4A | c.288T>A p.P96= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100557803; called by muse, mutect2, varscan2
- MST1R | c.114C>A p.R38= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as COSV99618735; called by muse, mutect2, varscan2
- MUC4 | c.1764G>A p.Q588= | Silent (SNP) | VAF 59/499 reads (12%) | catalogued as COSV62189880; called by muse, mutect2, varscan2
- MYBPC1 | c.2118T>C p.S706= (on ENST00000550270 / NM_206820.2; = p.S731= on NM_002465.4) | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV62252135; called by muse, mutect2, varscan2
- NCAM1 | c.1404C>A p.T468= (on ENST00000316851 / NM_181351.5; = p.T458= on NM_000615.7) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100377761; called by muse, mutect2, varscan2
- NCKAP1L | c.693C>T p.I231= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as rs768397510, COSV99515092; called by muse, mutect2, varscan2
- NISCH | c.3474G>C p.L1158= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100617335; called by muse, mutect2, varscan2
- NLRP13 | c.690G>A p.T230= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as rs574504902, COSV61619992; called by muse, mutect2, varscan2
- NRXN1 | c.4311G>A p.E1437= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100640265, COSV60499979; called by muse, mutect2, varscan2
- NTSR1 | c.477G>A p.V159= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV100980647; called by muse, mutect2, varscan2
- OFD1 | c.1473G>A p.K491= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs779135639, COSV100406924; called by muse, mutect2
- OR1C1 | c.630C>A p.P210= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV101376224; called by muse, mutect2, varscan2
- OR2AG2 | c.747G>T p.G249= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100643119; called by muse, mutect2, varscan2
- OR2AK2 | c.63C>A p.G21= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV100823678, COSV63560982; called by muse, mutect2, varscan2
- OR52R1 | c.534C>A p.P178= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV61889706; called by muse, mutect2, varscan2
- OR5D16 | c.717C>G p.V239= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV101003946, COSV65722925; called by muse, mutect2, varscan2
- PALLD | c.2961C>T p.I987= (on ENST00000505667 / NM_001166108.2; = p.I970= on NM_016081.4) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1484758238, COSV99824768; called by muse, mutect2, varscan2
- PIK3R4 | c.1401A>T p.I467= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV100768399; called by muse, mutect2, varscan2
- PLA2G4C | c.1392G>A p.V464= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as rs1312694886, COSV100843939; called by muse, mutect2, varscan2
- PLEKHG4B | c.600C>T p.S200= (on ENST00000283426; = p.S556= on NM_052909.5) | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as rs764802862, COSV104368969, COSV52050321, COSV99360521; called by muse, mutect2, varscan2
- PLXNB1 | c.5904C>A p.S1968= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV99602838; called by muse, mutect2, varscan2
- PLXNB3 | c.1746C>G p.T582= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100737451; called by muse, mutect2, varscan2
- PRSS23 | c.837C>T p.F279= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV99722413; called by muse, mutect2, varscan2
- PTCHD1 | c.2397A>G p.L799= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as COSV101037663; called by muse, mutect2, varscan2
- RAB24 | c.123C>T p.I41= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV57463195; called by muse, mutect2, varscan2
- RAB3IL1 | c.981G>A p.S327= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs376882014, COSV57117378; called by muse, mutect2
- RBBP9 | c.210C>T p.I70= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs1179411414, COSV100464051; called by muse, mutect2, varscan2
- RHEBL1 | c.36C>G p.L12= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV56504317; called by muse, mutect2
- RIN3 | c.279G>A p.S93= | Silent (SNP) | VAF 40/235 reads (17%) | catalogued as rs140939245, COSV53645232; called by muse, mutect2, varscan2
- RNF144A | c.858C>T p.D286= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs756316410, COSV57983044; called by muse, mutect2, varscan2
- RP1L1 | c.777G>A p.P259= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs369463692; called by muse, mutect2, varscan2
- RSF1 | c.3207A>G p.E1069= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV100407222; called by muse, mutect2, varscan2
- RSPO4 | c.324G>A p.K108= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV99449068; called by muse, mutect2, varscan2
- RTN1 | c.453A>T p.P151= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV50730980; called by muse, mutect2, varscan2
- RYR1 | c.9210C>T p.I3070= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100615735; called by muse, mutect2, varscan2
- SALL3 | c.2406G>A p.E802= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV73305781; called by muse, mutect2, varscan2
- SH3KBP1 | c.1179C>G p.P393= | Silent (SNP) | VAF 138/339 reads (41%) | catalogued as COSV101114764; called by muse, mutect2, varscan2
- SLC22A11 | c.66C>G p.L22= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV100102338; called by muse, mutect2, varscan2
- SLC31A1 | c.24G>A p.G8= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100951922; called by muse, mutect2, varscan2
- SLC34A3 | c.1410C>T p.P470= | Silent (SNP) | VAF 35/157 reads (22%) | catalogued as COSV100746661; called by muse, mutect2, varscan2
- SLIT3 | c.1893G>T p.V631= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100267476; called by muse, mutect2, varscan2
- SPACA1 | c.597C>G p.V199= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1401668967, COSV99389528; called by muse, mutect2, varscan2
- SPG21 | c.687G>A p.A229= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs762934056, COSV99200189; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTA1 | c.6093G>A p.L2031= | Silent (SNP) | VAF 27/189 reads (14%) | catalogued as rs777450022, COSV100934964, COSV63758830, COSV63760737; called by muse, mutect2, varscan2
- STAC | c.1020G>A p.Q340= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99830015; called by muse, mutect2, varscan2
- STAT2 | c.1071G>C p.L357= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV100028898; called by muse, mutect2, varscan2
- STXBP2 | c.1008C>T p.Y336= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV99657154; called by muse, mutect2, varscan2
- SWT1 | c.1479C>T p.L493= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100833304; called by muse, mutect2
- SYNE2 | c.7959G>C p.L2653= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV100647677; called by muse, mutect2, varscan2
- TDRD7 | c.165T>C p.S55= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs1343906963, COSV100795624; called by muse, mutect2, varscan2
- TNPO3 | c.2067G>C p.V689= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99602959; called by muse, mutect2, varscan2
- TTN | c.99315G>C p.L33105= (on ENST00000591111; = p.L25681= on NM_003319.4) | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100612807; called by muse, mutect2, varscan2
- TUB | c.846C>T p.P282= (on ENST00000299506 / NM_177972.3; = p.P337= on NM_003320.4) | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV100210211; called by muse, mutect2, varscan2
- TUBA1B | c.663C>A p.R221= | Silent (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- UNC80 | c.162A>T p.V54= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV99779574; called by muse, mutect2, varscan2
- USH2A | c.7308T>C p.D2436= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100234709; called by muse, mutect2, varscan2
- UXT | c.9G>C p.T3= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV100243841; called by muse, mutect2, varscan2
- VANGL2 | c.207G>T p.G69= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV100925572; called by muse, mutect2
- VPS26B | c.84G>A p.K28= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs770338586, COSV99845007; called by muse, mutect2, varscan2
- WDR75 | c.693G>A p.R231= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV59105384; called by muse, mutect2
- WDR90 | c.4998G>A p.Q1666= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99553414; called by muse, mutect2, varscan2
- WNT8A | c.675G>A p.L225= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV64230969; called by muse, mutect2, varscan2
- XK | c.529C>T p.L177= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV101064666; called by muse, mutect2, varscan2
- ZFP2 | c.429C>T p.S143= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1466554380, COSV100797056; called by muse, mutect2
- ZFP69 | c.1428T>C p.Y476= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV101018237; called by muse, mutect2, varscan2
- ZIC1 | c.696C>A p.P232= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV51556274, COSV99291929; called by muse, mutect2, varscan2
- ZNF260 | c.315C>T p.H105= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV101591057; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504017 G>A | 5'Flank (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- BTN2A3P | n.1389C>T | RNA (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- KCNIP3 | c.182-27220C>A | Intron (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99734118; called by muse, mutect2, varscan2
- MFRP | chr11:119346053 G>A | 5'Flank (SNP) | VAF 9/20 reads (45%) | catalogued as rs1031316533, COSV100793438; called by muse, mutect2, varscan2
- NEBL | c.164+46458G>T | Intron (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791031 C>G | 5'Flank (SNP) | VAF 29/158 reads (18%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.127-9401A>C | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as COSV101084390; called by muse, mutect2
- SNORD116-11 | n.21A>C | RNA (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- SSPOP | n.9197C>T | RNA (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100947416; called by muse, mutect2, varscan2
- TRIOBP | c.6324+153C>T | Intron (SNP) | VAF 47/223 reads (21%) | catalogued as rs376167819; called by muse, varscan2
- Y_RNA | chr7:75511079 T>A | 3'Flank (SNP) | VAF 29/165 reads (18%) | called by muse, mutect2, varscan2
